Somatic mutation profile of tumor specimen TCGA-W5-AA2I-01A (aliquot TCGA-W5-AA2I-01A-32D-A417-09) from TCGA case TCGA-W5-AA2I, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 66.8 years (24,388 days).
Specimen TCGA-W5-AA2I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0774742-cc0f-460e-9ac4-d8422dcec40c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W5-AA2I-10A (Blood Derived Normal), aliquot TCGA-W5-AA2I-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/835879ba-0c62-4009-824e-a8899958926f

The open-access MAF lists 45 somatic variants for this specimen: 41 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 34, Silent 4, Frame Shift Del 4, Nonsense Mutation 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.5640T>A p.Y1880* | Nonsense Mutation (SNP) | VAF 12/16 reads (75%) | catalogued as rs398123993; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.421T>C p.C141R | Missense Mutation (SNP) | VAF 7/12 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519978, COSV52675559, COSV52751154, COSV52796306, COSV53037181; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALB | c.919del p.L307Cfs*23 | Frame Shift Del (DEL) | VAF 42/100 reads (42%) | catalogued as COSV99071650; called by mutect2, pindel, varscan2
- BLK | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751424817; called by muse, mutect2, varscan2
- CADM2 | c.776T>C p.V259A (on ENST00000407528 / NM_001167674.2; = p.V261A on NM_153184.4) | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1167804933; called by muse, mutect2, varscan2
- CEP350 | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs1158900004; called by muse, mutect2, varscan2
- CPD | c.2818T>C p.S940P | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as rs1269573535; called by muse, mutect2, varscan2
- CPLX4 | c.469T>A p.C157S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV55313844; called by muse, mutect2, varscan2
- DCAF4L2 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1302039232, COSV60481056; called by muse, mutect2, varscan2
- KCNQ3 | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs138181943; called by muse, mutect2, varscan2
- MME | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1297718264; called by muse, mutect2, varscan2
- MUC5B | c.2755T>G p.Y919D | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101500358; called by muse, mutect2, varscan2
- MUC5B | c.14972C>T p.P4991L | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs377111871; called by muse, mutect2, varscan2
- PCLO | c.3391G>C p.G1131R | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.246); catalogued as COSV100436374; called by muse, mutect2
- RIOK2 | c.811G>T p.D271Y | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as rs972636429; called by muse, mutect2, varscan2
- SMARCAL1 | c.1976G>A p.R659H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs568131335; called by muse, varscan2
- TRAP1 | c.512A>G p.N171S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as rs759416487; called by muse, mutect2, varscan2
- UBR1 | c.4969G>A p.A1657T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.996); catalogued as rs550798440, COSV51927628; called by muse, mutect2, varscan2
- UCKL1 | c.233C>T p.T78I | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); catalogued as rs1332297307; called by muse, mutect2, varscan2
- ZNF233 | c.1002_1003del p.R334Sfs*27 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | catalogued as rs1480350809; called by pindel, varscan2
- ZNF536 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs941188446, COSV100835611; called by muse, mutect2
- ACTC1 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DLK1 | c.1055A>C p.Q352P | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- EPHA2 | c.2828A>T p.D943V | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPRS1 | c.4013A>T p.N1338I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- FEZ1 | c.47G>C p.R16P | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- GABRB3 | c.1325T>G p.L442R | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.411); called by muse, mutect2
- HHLA2 | c.140del p.I47Kfs*14 | Frame Shift Del (DEL) | VAF 24/75 reads (32%) | called by mutect2, pindel, varscan2
- HSF5 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- KLHL11 | c.1826A>G p.D609G | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MAGED1 | c.1453A>T p.K485* | Nonsense Mutation (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- PBRM1 | c.3053_3054insATT p.V1017_F1018insL (on ENST00000296302 / NM_001366071.2; = p.V992_F993insL on NM_018313.5) | In Frame Ins (INS) | VAF 27/43 reads (63%) | called by mutect2, pindel, varscan2
- PCDH11X | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- PEPD | c.669A>C p.E223D | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SPATA4 | c.398C>T p.T133I | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPATS2 | c.1133A>G p.Y378C | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRCAP | c.1027_1034del p.L343Rfs*13 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- SSU72P8 | c.359T>G p.V120G | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- TAS2R31 | c.736A>C p.M246L | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2
- TRIP12 | c.2253G>C p.K751N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ZNF691 | c.703A>T p.S235C (on ENST00000372502; = p.S204C on NM_015911.3) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.972); called by muse, mutect2
- CHI3L1 | c.912C>T p.R304= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs774198485, COSV55137983; called by muse, mutect2
- FAM71F2 | c.222T>C p.S74= | Silent (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- NEUROD1 | c.867G>A p.P289= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs780843075, COSV54547992; called by muse, mutect2, varscan2
- UBN2 | c.3810C>G p.P1270= | Silent (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
